Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8104, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8104-01A (Primary Tumor).

Pathology Report for Subject: [REDACTED]

Diagnosis: Anaplastic Astrocytoma (grade III)

Microscopic Description: Sections demonstrate a markedly hypercellular glial neoplasm that is composed of cells resembling moderately atypical fibrillary astrocytes. Scattered mitotic figures are seen with 11 mitoses seen in 10 high power fields. There is no microvascular proliferation or necrosis. Definite oligodendroglioma differentiation is not seen.

Source: NCI Genomic Data Commons file 1e263952-6a34-4615-ba55-c89545699335 (TCGA-HT-8104.BE808788-D11D-4E91-8B52-6D830D1CB5CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).